Gene-level copy-number profile of tumor specimen TCGA-39-5031-01A from TCGA case TCGA-39-5031, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.0 years (28,106 days).
Specimen TCGA-39-5031-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e47e6446-f16f-4055-9689-c42b00e2e7b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5031-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a89d13c-ac0d-4f25-ba9b-a68e01a73ced

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 21; copy number 2: 3,303; copy number 3: 13,546; copy number 4: 22,702; copy number 5: 4,411; copy number 6: 9,022; copy number 7: 3,218; copy number 8: 1,488; copy number 10: 454; copy number 11: 164; copy number 12: 700; copy number 14: 24; copy number 16: 75; copy number 18: 543; copy number 19: 11; copy number 23: 24; copy number 29: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5031-01A-01D-1439-01): tumor purity 0.4, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,999,691–213,152,427, 1 gene (within-gene range 0–4): IKZF2.
- chr7:149,321,865–149,734,575, 8 genes (within-gene range 0–2): AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,094 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:44,921,077–64,019,428, 295 genes, copy number 12–29 (within-gene range 8–29) (broad region; genes not listed).
- chr3:135,925,891–198,222,513, 1,088 genes, copy number 10–18 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 12–23 (broad region; genes not listed).
- chr7:146,050,062–146,050,366, 1 gene, copy number 12: AC073308.1.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
